Gene-level copy-number profile of tumor specimen TCGA-B6-A0RM-01A from TCGA case TCGA-B6-A0RM, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage X; Age at diagnosis: 57.6 years (21,047 days).
Specimen TCGA-B6-A0RM-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BRCA.4a733db9-a92f-457b-b0ef-25a0722e9d44.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-B6-A0RM-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/a1ec71b2-291c-4d1e-a069-a87ac79ddaad

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 1,706; copy number 2: 54,685; copy number 3: 94; copy number 4: 1,584; copy number 6: 219; copy number 7: 1,532.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-B6-A0RM-01A-11D-A087-01): tumor purity 0.83, ploidy 2.16, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,751 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:35,080,592–145,066,685, 1,727 genes, copy number 6–7 (broad region; genes not listed).
- chr16:49,282,021–50,107,272, 24 genes, copy number 6 (within-gene range 4–6): AC007614.1, AC007614.2, C16orf78, AC007861.1, AC007861.2, LINC02179, ZNF423, ADAM3B, MRPS21P7, AC027348.2, MRPS21P8, AC027348.1, AC007603.2, AC007603.1, RPL34P29, AC007603.3, CNEP1R1, AC007610.1, AC007610.3, Metazoa_SRP, ACTG1P16, HEATR3, AC007610.4, RNY4P3.

Autosomal genes at a single copy (total copy number 1): 1,706. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
